Somatic mutation profile of tumor specimen MP2PRT-PAVNVK-TMP1-A (aliquot MP2PRT-PAVNVK-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVNVK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,696 days).
Specimen MP2PRT-PAVNVK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e52db0d4-b6ec-48be-99c8-fa8ad255dd1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNVK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNVK-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2270ab4d-d2e6-4e0f-9f3d-31508d2fd68f

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP4 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 78/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005176163, COSV54519289; called by muse, varscan2
- ANKH | c.909delinsAGA p.F303Lfs*12 | Frame Shift Ins (INS) | VAF 67/366 reads (18%) | catalogued as COSV52478606; called by pindel, varscan2*
- FBP2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 102/189 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs529636593; called by muse, mutect2, varscan2
- HMCN2 | c.14632C>T p.R4878C | Missense Mutation (SNP) | VAF 146/452 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs189955406; called by muse, mutect2, varscan2
- SCART1 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); catalogued as rs561360433; called by muse, mutect2, varscan2
- TTN | c.6367C>T p.R2123W (on ENST00000591111; = p.R2077W on NM_003319.4) | Missense Mutation (SNP) | VAF 181/522 reads (35%) | PolyPhen probably damaging (0.999); catalogued as rs777316854, COSV59955587; called by muse, mutect2, varscan2
- CBLB | c.1415_1416insGGG p.D472delinsEG | In Frame Ins (INS) | VAF 86/265 reads (32%) | called by mutect2, pindel*, varscan2
- FBN3 | c.7852C>A p.R2618S | Missense Mutation (SNP) | VAF 218/640 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2
- IQSEC3 | c.2250G>T p.K750N (on ENST00000538872 / NM_001170738.2; = p.K447N on NM_015232.1) | Missense Mutation (SNP) | VAF 169/684 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRMT6 | c.835T>A p.C279S | Missense Mutation (SNP) | VAF 245/665 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PUS7L | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TSPY8 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 148/354 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM171B | c.2337G>A p.S779= | Silent (SNP) | VAF 32/456 reads (7%) | catalogued as rs773774867, COSV59002008; called by muse, mutect2
- IGHV1-45 | c.353delinsCC p.*118S | Silent (INS) | VAF 65/148 reads (44%) | called by mutect2*, pindel, varscan2*
- MS4A4E | c.249G>A p.A83= | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as rs562944261, COSV67518377; called by muse, mutect2, varscan2
- MYH8 | c.3564T>C p.H1188= | Silent (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- SIRPB2 | c.876C>T p.F292= | Silent (SNP) | VAF 43/338 reads (13%) | catalogued as rs751120893; called by muse, mutect2, varscan2
- SPTA1 | c.1674C>T p.D558= | Silent (SNP) | VAF 78/293 reads (27%) | catalogued as rs780161347, COSV63750189; called by muse, mutect2, varscan2
- TRO | c.4068C>A p.G1356= | Silent (SNP) | VAF 36/345 reads (10%) | called by muse, mutect2, varscan2
